Somatic mutation profile of tumor specimen MP2PRT-PAUCIG-TMP1-A (aliquot MP2PRT-PAUCIG-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUCIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (785 days).
Specimen MP2PRT-PAUCIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba2c723a-1b09-4d9a-b58e-87f2425de463.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCIG-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ba2c63e-7846-4ac2-b33c-b2ed0a7de0e0

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, 3'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 52/195 reads (27%) | catalogued as rs121908378, CM051480, COSV100647565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SP5 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 88/719 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs372466407; called by muse, mutect2, varscan2
- TAS2R7 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 91/663 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs757204228, COSV53687801; called by muse, mutect2, varscan2
- TCF3 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 20/656 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV53649349; called by muse, mutect2
- TMEM177 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 216/617 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1187499729; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 226/715 reads (32%) | called by mutect2, pindel, varscan2
- H2BC11 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 118/337 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- INTS5 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 18/581 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2
- UNC13C | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- AP3B2 | c.3246G>C p.V1082= (on ENST00000261722; = p.V1076= on NM_004644.5) | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as COSV99917133; called by muse, mutect2
- FAM169A | c.390G>A p.E130= | Silent (SNP) | VAF 45/395 reads (11%) | called by muse, mutect2, varscan2
- GPRASP2 | c.1323G>A p.P441= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as rs200445301; called by muse, mutect2, varscan2
- NDN | c.399G>A p.K133= | Silent (SNP) | VAF 55/445 reads (12%) | catalogued as COSV59361858; called by muse, mutect2, varscan2
- NTN1 | c.1125C>T p.T375= | Silent (SNP) | VAF 207/540 reads (38%) | catalogued as rs751598491; called by muse, mutect2, varscan2
- RHBDF2 | c.2196C>T p.F732= | Silent (SNP) | VAF 39/507 reads (8%) | catalogued as rs113933508; called by muse, mutect2
- SLCO2A1 | chr3:133928587 C>G | 3'Flank (SNP) | VAF 70/629 reads (11%) | catalogued as COSV100188695, COSV60485800; called by muse, mutect2, varscan2
